Gene-level copy-number profile of specimen HCM-SANG-1335-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-1335-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1335-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cb286962-8b3d-492d-afb3-777644af8bd5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1335-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/8f160eb8-1fce-4f39-82eb-3c99a3b56c30

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,161; copy number 2: 51,478; copy number 3: 1,516; copy number 4: 1,926; copy number 5: 1,770; copy number 8: 59.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,829 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:30,082,758–34,346,731, 74 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:36,784,324–39,417,378, 73 genes, copy number 5 (broad region; genes not listed).
- chr8:39,522,976–145,066,685, 1,595 genes, copy number 5 (broad region; genes not listed).
- chr15:21,927,657–21,946,641, 1 gene, copy number 5: NF1P2.
- chr20:20,854,121–20,854,642, 1 gene, copy number 5: MRPS11P1.
- chr20:21,085,576–21,246,622, 8 genes, copy number 5: LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1.
- chr20:30,214,765–32,743,567, 77 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,153. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
